Somatic mutation profile of tumor specimen TCGA-WC-A88A-01A (aliquot TCGA-WC-A88A-01A-11D-A39W-08) from TCGA case TCGA-WC-A88A, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.9 years (27,722 days).
Specimen TCGA-WC-A88A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a929d5e0-ad8f-48c6-ae85-c62b6e8420be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A88A-10A (Blood Derived Normal), aliquot TCGA-WC-A88A-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b4e02e5-c502-4ea0-b744-9d91914f8075

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BNC1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1396582148; called by muse, mutect2, varscan2
- NOC4L | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs529616528, COSV57958444; called by muse, mutect2, varscan2
- PLCB2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1242886355; called by muse, mutect2, varscan2
- PPARA | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as rs764930526, COSV53077323; called by muse, mutect2, varscan2
- PRDM11 | c.428C>G p.A143G (on ENST00000530656 / NM_001359633.1; = p.A109G on NM_001256695.1) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55440423; called by muse, mutect2, varscan2
- ZSCAN16 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs773429225; called by muse, mutect2, varscan2
- DR1 | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GAL3ST4 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SCARB1 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.284); called by muse, mutect2
- SVEP1 | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CPEB1 | c.1539A>G p.L513= (on ENST00000617958; = p.L448= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs368407272; called by muse, mutect2, varscan2
